Gene-level copy-number profile of specimen HCM-CSHL-0462-D05-85T from HCMI case HCM-CSHL-0462-D05, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Intraductal carcinoma, noninfiltrating, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage 0; Tumor grade: GX; Age at diagnosis: 49.1 years (17,939 days).
Specimen HCM-CSHL-0462-D05-85T: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4864e071-c893-48b1-9ee0-6255dfa77e45.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0462-D05-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/4123eec5-3802-4209-8ecf-81a97eb5a70c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 1,122; copy number 2: 54,634; copy number 3: 2,647.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:55,760,566–55,793,960, 1 gene: CES1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,122. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
